Somatic mutation profile of tumor specimen 0DKSWT from CCDI case PBBYTS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 3.2 years (1,155 days).
Specimen 0DKSWT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f03e1235-31cd-4049-8887-32a19913cf09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKSTX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cf9214d-ed78-4e94-9c40-10ffe55d6170

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Nonsense Mutation 1, Frame Shift Ins 1, Silent 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 506/1181 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 717/1299 reads (55%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.2525A>T p.D842V | Missense Mutation (SNP) | VAF 600/1366 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908585, COSV57264120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 111/1012 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASH1L | c.3701C>A p.P1234H | Missense Mutation (SNP) | VAF 303/1729 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FBXO43 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 991/1702 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KAT6A | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 233/1767 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR56A3 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 702/1665 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- PDGFRA | c.3142dup p.S1048Kfs*4 | Frame Shift Ins (INS) | VAF 333/1479 reads (23%) | called by mutect2, pindel, varscan2
- PPM1D | c.1519_1520del p.V507Hfs*20 | Frame Shift Del (DEL) | VAF 1362/2968 reads (46%) | called by mutect2, pindel, varscan2
- RBM6 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 313/1104 reads (28%) | called by muse, mutect2, varscan2
- FAT4 | c.10506G>T p.L3502= | Silent (SNP) | VAF 137/1124 reads (12%) | called by mutect2, varscan2
- CDYL | c.*27G>A | 3'UTR (SNP) | VAF 284/686 reads (41%) | catalogued as rs755885510, COSV100189861; called by muse, mutect2, varscan2
- CLN3 | c.462-9C>G | Intron (SNP) | VAF 204/520 reads (39%) | called by muse, mutect2, varscan2
- MIA3 | c.4874+33C>T | Intron (SNP) | VAF 226/2808 reads (8%) | catalogued as rs750147532; called by muse, mutect2
- XPNPEP2 | c.490+59C>A | Intron (SNP) | VAF 33/285 reads (12%) | called by muse, mutect2, varscan2
